Somatic mutation profile of tumor specimen C3L-02165-01 (aliquot CPT0129910006) from CPTAC case C3L-02165, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 64.8 years (23,666 days).
Specimen C3L-02165-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 98e0646d-4924-4ba6-857e-b399aa0a7a95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02165-31 (Blood Derived Normal), aliquot CPT0130010002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2260785e-8e5e-447f-b54e-92b0a1aecbe6

The open-access MAF lists 496 somatic variants for this specimen: 339 protein-altering or splice-affecting, 110 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 289, Silent 110, Nonsense Mutation 18, Intron 18, Frame Shift Del 12, Splice Site 10, RNA 10, 3'UTR 6, 5'UTR 5, Splice Region 5, 5'Flank 4, Frame Shift Ins 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 36/196 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.872G>T p.W291L | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65316134; called by muse, mutect2, varscan2
- ABCC8 | c.949C>A p.P317T | Missense Mutation (SNP) | VAF 68/394 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56856353; called by muse, mutect2, varscan2
- ACHE | c.492C>A p.Y164* | Nonsense Mutation (SNP) | VAF 18/214 reads (8%) | catalogued as COSV99573618; called by muse, mutect2
- ADAD1 | c.226G>T p.V76F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.208); catalogued as COSV99635638; called by muse, mutect2, varscan2
- ADCY4 | c.3047G>A p.R1016H | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs151266711; called by muse, mutect2, varscan2
- AFF3 | c.2301G>T p.W767C | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1272347484, COSV57862194; called by muse, mutect2, varscan2
- AGTR1 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62560716; called by muse, mutect2, varscan2
- AMY2A | c.867G>A p.M289I | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.355); catalogued as COSV101340659; called by mutect2, varscan2
- ATP2B1 | c.139C>G p.R47G | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99665093; called by muse, mutect2, varscan2
- BRINP2 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64177196; called by muse, mutect2, varscan2
- C10orf71 | c.2941G>A p.V981M | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1046033025, COSV60512018; called by muse, mutect2, varscan2
- C5orf49 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV67708369, COSV67709715; called by muse, mutect2
- C9orf135 | c.36C>A p.C12* | Nonsense Mutation (SNP) | VAF 43/153 reads (28%) | catalogued as rs370333172; called by muse, mutect2, varscan2
- CADM2 | c.346G>T p.A116S (on ENST00000407528 / NM_001167674.2; = p.A118S on NM_153184.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.997); catalogued as COSV67378380; called by muse, mutect2
- CCSER1 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as rs369591675; called by muse, mutect2, varscan2
- CLDN25 | c.16C>A p.R6S | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.441); catalogued as COSV71620433, COSV71620507; called by muse, varscan2
- CNBD1 | c.88A>T p.N30Y | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as COSV72917343; called by muse, mutect2, varscan2
- CRB1 | c.3020G>C p.R1007T | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.966); catalogued as COSV66333330; called by muse, mutect2, varscan2
- CSMD2 | c.9590C>A p.T3197K | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV53944804; called by muse, mutect2, varscan2
- CSMD3 | c.4487G>C p.S1496T (on ENST00000297405 / NM_001363185.1; = p.S1392T on NM_052900.3) | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs770184805, COSV52183326; called by muse, mutect2, varscan2
- CSMD3 | c.2402C>T p.T801I (on ENST00000297405 / NM_001363185.1; = p.T697I on NM_052900.3) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs953385252; called by muse, mutect2, varscan2
- CTNND2 | c.2531C>A p.P844Q | Missense Mutation (SNP) | VAF 39/219 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100479616; called by muse, mutect2, varscan2
- DDX60 | c.2380G>T p.A794S | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV67099651; called by muse, mutect2, varscan2
- DEPDC5 | c.2279G>T p.R760L (on ENST00000400246; = p.R829L on NM_014662.5) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV56693547; called by muse, mutect2, varscan2
- ENOX1 | c.893G>T p.R298L | Missense Mutation (SNP) | VAF 60/338 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54894307, COSV54899477; called by muse, varscan2
- EPHA5 | c.2528G>C p.R843T | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56669002, COSV99899468; called by muse, mutect2, varscan2
- EXTL2 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV64473108; called by muse, varscan2
- FAT3 | c.12005G>T p.R4002L | Missense Mutation (SNP) | VAF 53/307 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); catalogued as COSV53129249; called by muse, mutect2, varscan2
- FBXL7 | c.1147delinsCC p.A383Pfs*73 | Frame Shift Ins (INS) | VAF 38/231 reads (16%) | catalogued as COSV61641324; called by mutect2*, pindel, varscan2*
- FLG | c.2247C>G p.D749E | Missense Mutation (SNP) | VAF 122/831 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.143); catalogued as rs1423050582; called by muse, mutect2, varscan2
- FZD10 | c.1378G>T p.A460S | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.853); catalogued as COSV57473463, COSV57474920; called by muse, mutect2, varscan2
- GAK | c.1205+1G>T p.X402_splice | Splice Site (SNP) | VAF 13/81 reads (16%) | catalogued as COSV58505187; called by muse, varscan2
- GRAMD2B | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs773306903; called by muse, mutect2, varscan2
- HELZ | c.4051G>C p.A1351P | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV62378844; called by muse, mutect2, varscan2
- HK3 | c.234C>A p.Y78* | Nonsense Mutation (SNP) | VAF 26/165 reads (16%) | catalogued as COSV99457707; called by muse, mutect2, varscan2
- IFT140 | c.3779G>T p.R1260L | Missense Mutation (SNP) | VAF 31/298 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV63697499; called by muse, mutect2, varscan2
- IGKV2D-29 | c.137G>T p.S46I | Missense Mutation (SNP) | VAF 43/261 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as rs772946535; called by muse, mutect2, varscan2
- INHBA | c.1270G>T p.G424W | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs894989688; called by muse, varscan2
- KCNA4 | c.52C>A p.P18T | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs749018764; called by muse, mutect2, varscan2
- KCNJ5 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 79/466 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as rs1258137665, COSV57969327; called by muse, mutect2, varscan2
- KDM4E | c.1327C>A p.R443S | Missense Mutation (SNP) | VAF 55/289 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.726); catalogued as rs1022334485; called by muse, mutect2, varscan2
- KMT2B | c.3003-5C>T | Splice Region (SNP) | VAF 9/46 reads (20%) | catalogued as rs1218204174; called by muse, mutect2
- KRTAP19-1 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 31/517 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.36); catalogued as rs755686961; called by muse, mutect2
- LAMA3 | c.1610G>T p.W537L | Missense Mutation (SNP) | VAF 75/416 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV100557249; called by muse, mutect2, varscan2
- LILRB5 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 51/333 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.502); catalogued as rs1322590859; called by muse, mutect2, varscan2
- LRRC32 | c.1569G>T p.E523D | Missense Mutation (SNP) | VAF 39/277 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV52632171; called by muse, mutect2, varscan2
- MGAM | c.5086G>T p.E1696* | Nonsense Mutation (SNP) | VAF 52/281 reads (19%) | catalogued as rs1268266008; called by muse, mutect2, varscan2
- MTUS2 | c.3640G>T p.E1214* (on ENST00000612955 / NM_001366650.1; = p.E193* on NM_015233.6) | Nonsense Mutation (SNP) | VAF 44/231 reads (19%) | catalogued as COSV66420118, COSV66421290; called by muse, mutect2, varscan2
- MYLK3 | c.1088A>G p.E363G | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs1236218372; called by muse, mutect2, varscan2
- NLRP12 | c.1402G>C p.G468R | Missense Mutation (SNP) | VAF 77/527 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60743553; called by muse, mutect2, varscan2
- NLRP5 | c.1361G>T p.G454V | Missense Mutation (SNP) | VAF 45/309 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1295425412; called by muse, mutect2, varscan2
- NRXN3 | c.326G>T p.R109L (on ENST00000557594 / NM_001272020.2; = p.R741L on NM_004796.6) | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55349261; called by muse, mutect2, varscan2
- OCA2 | c.573+1G>C p.X191_splice | Splice Site (SNP) | VAF 84/466 reads (18%) | catalogued as COSV100667845, COSV100668221; called by muse, mutect2, varscan2
- OR2L2 | c.793C>G p.R265G | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as COSV63547603; called by muse, mutect2, varscan2
- OR52R1 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 36/214 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs903426846, COSV61888520; called by muse, mutect2, varscan2
- OR5K4 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201188789; called by muse, mutect2, varscan2
- P3H2 | c.1817+6G>A | Splice Region (SNP) | VAF 40/226 reads (18%) | catalogued as rs773292642, COSV60022032; called by muse, mutect2, varscan2
- PCDH11Y | c.1645C>A p.R549S (on ENST00000400457 / NM_032973.2; = p.R538S on NM_032971.3) | Missense Mutation (SNP) | VAF 30/193 reads (16%) | SIFT tolerated (0.47); PolyPhen benign (0.075); catalogued as COSV53074243; called by muse, mutect2, varscan2
- PCDHA11 | c.428C>A p.A143E | Missense Mutation (SNP) | VAF 46/257 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.644); catalogued as rs782191099, COSV56514327; called by muse, mutect2, varscan2
- PCDHA3 | c.1856G>T p.R619L | Missense Mutation (SNP) | VAF 34/342 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.365); catalogued as COSV63540056; called by muse, mutect2
- PCDHGA1 | c.263G>T p.R88L | Missense Mutation (SNP) | VAF 40/234 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.232); catalogued as rs1412446548; called by muse, mutect2, varscan2
- PCDHGA4 | c.862G>A p.V288I | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.071); catalogued as rs1359465657; called by muse, mutect2, varscan2
- PDE3A | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV100761923; called by muse, mutect2, varscan2
- PIKFYVE | c.4679G>T p.R1560L | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV52244211; called by muse, mutect2, varscan2
- PKD1 | c.9806G>T p.R3269L | Missense Mutation (SNP) | VAF 144/768 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs550467690, COSV51919121; called by muse, mutect2, varscan2
- POGLUT3 | c.331G>A p.D111N | Missense Mutation (SNP) | VAF 10/150 reads (7%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs772803484; called by muse, mutect2
- PPFIA1 | c.1073G>T p.R358L | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV99557348; called by muse, mutect2, varscan2
- PPP1R9A | c.2681G>T p.R894I | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV99199077; called by muse, mutect2
- PTPRD | c.1466C>A p.S489Y | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.096); catalogued as COSV61962073; called by muse, mutect2, varscan2
- PTPRN2 | c.88G>T p.G30C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as rs1358880075; called by muse, mutect2, varscan2
- RINL | c.1573C>G p.R525G (on ENST00000591812 / NM_001195833.2; = p.R411G on NM_198445.4) | Missense Mutation (SNP) | VAF 23/174 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV61574165; called by muse, mutect2, varscan2
- RNASE3 | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 76/464 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.082); catalogued as rs202232277, COSV58960010; called by muse, mutect2, varscan2
- RP1L1 | c.6643C>A p.P2215T | Missense Mutation (SNP) | VAF 159/686 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs757422919; called by muse, mutect2, varscan2
- RPS4Y2 | c.299G>A p.R100H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); catalogued as rs1351667080; called by muse, mutect2, varscan2
- RYR2 | c.4668G>T p.E1556D | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs370332700; called by muse, mutect2, varscan2
- SCN2A | c.4053C>A p.F1351L | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99330628; called by muse, mutect2, varscan2
- SCN9A | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 66/370 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.175); catalogued as rs754646586; called by muse, mutect2, varscan2
- SERPINA7 | c.1114C>A p.L372I | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0.013); catalogued as CD910556; called by muse, mutect2, varscan2
- SETD7 | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs781195118; called by muse, mutect2, varscan2
- SIGLEC10 | c.775G>A p.G259R | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as COSV100219371; called by muse, mutect2, varscan2
- SLC38A2 | c.845G>T p.R282I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.106); catalogued as rs1053037702; called by muse, mutect2, varscan2
- SLC5A8 | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.013); catalogued as COSV73310477; called by muse, mutect2, varscan2
- SLC6A5 | c.584C>A p.S195Y | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1453189200; called by muse, mutect2, varscan2
- TAF3 | c.2019G>T p.R673S | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.122); catalogued as COSV100720574, COSV60204696; called by muse, mutect2, varscan2
- TANC2 | c.5233C>T p.P1745S | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.979); catalogued as rs1311730519; called by muse, mutect2, varscan2
- TEX15 | c.1828C>T p.P610S (on ENST00000256246; = p.P993S on NM_001350162.2) | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.276); catalogued as rs751632620; called by muse, mutect2, varscan2
- TMCC2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 83/331 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.848); catalogued as rs779837835; called by muse, mutect2, varscan2
- TMEM132C | c.218G>T p.R73L | Missense Mutation (SNP) | VAF 28/155 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs545431831; called by muse, mutect2, varscan2
- TMEM63B | c.2273G>T p.R758L | Missense Mutation (SNP) | VAF 23/173 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs1221158138, COSV52477624; called by muse, mutect2, varscan2
- TNKS | c.3714G>T p.K1238N | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV60068017; called by muse, mutect2, varscan2
- TRIM25 | c.1180+1G>T p.X394_splice | Splice Site (SNP) | VAF 10/53 reads (19%) | catalogued as COSV57543910; called by muse, mutect2, varscan2
- TRIM55 | c.274G>A p.V92I | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV52543865, COSV52545931; called by muse, mutect2, varscan2
- TRIP10 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57570946; called by muse, mutect2
- TTN | c.40298G>T p.G13433V (on ENST00000591111; = p.G6009V on NM_003319.4) | Missense Mutation (SNP) | VAF 48/292 reads (16%) | PolyPhen probably damaging (1); catalogued as COSV60078126; called by muse, mutect2, varscan2
- TUBB4A | c.548A>G p.Y183C | Missense Mutation (SNP) | VAF 36/648 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99899875; called by muse, mutect2
- UNC13A | c.727A>G p.M243V | Missense Mutation (SNP) | VAF 56/319 reads (18%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as rs759013861; called by muse, mutect2, varscan2
- UNC5C | c.282G>T p.K94N | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV71658427; called by muse, mutect2, varscan2
- UPK1A | c.563del p.P188Hfs*54 | Frame Shift Del (DEL) | VAF 28/170 reads (16%) | catalogued as rs896634037; called by mutect2, varscan2
- VWA3B | c.2875G>T p.E959* | Nonsense Mutation (SNP) | VAF 25/132 reads (19%) | catalogued as COSV68241032; called by muse, mutect2, varscan2
- WDR7 | c.4400G>T p.R1467L | Missense Mutation (SNP) | VAF 32/351 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54366655, COSV99589433; called by muse, mutect2
- WNT11 | c.797G>T p.R266L | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV59443668; called by muse, mutect2, varscan2
- XIRP2 | c.5712G>C p.M1904I (on ENST00000628543; = p.M2079I on NM_152381.6) | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV54699138; called by muse, mutect2, varscan2
- YIPF3 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.007); catalogued as rs551252405; called by muse, mutect2
- ZNF610 | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.562); catalogued as rs759409003; called by muse, mutect2, varscan2
- ZNF804A | c.2646C>A p.H882Q | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0.027); catalogued as COSV56453306; called by muse, mutect2, varscan2
- ZNF835 | c.1092C>A p.C364* | Nonsense Mutation (SNP) | VAF 20/263 reads (8%) | catalogued as COSV73379276; called by muse, mutect2
- ABL1 | c.1270+1dup | Frame Shift Ins (INS) | VAF 10/92 reads (11%) | called by mutect2, varscan2
- ACOD1 | c.552C>A p.C184* | Nonsense Mutation (SNP) | VAF 54/270 reads (20%) | called by muse, mutect2, varscan2
- ADAM10 | c.681G>T p.Q227H | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- ADCY1 | c.2671G>T p.V891L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- ADCY10 | c.1696G>C p.G566R | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADCY2 | c.22C>A p.R8S | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADCY4 | c.2872A>T p.T958S | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADCY8 | c.3281del p.G1094Afs*4 | Frame Shift Del (DEL) | VAF 29/118 reads (25%) | called by mutect2, pindel
- ADGRG5 | c.667T>A p.C223S | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADRA2A | c.859C>A p.Q287K | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ANK2 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD34C | c.384del p.N128Kfs*8 | Frame Shift Del (DEL) | VAF 14/71 reads (20%) | called by mutect2, pindel, varscan2
- ANKRD37 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKRD44 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ANO4 | c.682C>A p.L228M (on ENST00000392977 / NM_001286615.2; = p.L193M on NM_178826.4) | Missense Mutation (SNP) | VAF 41/205 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- APC | c.6703G>T p.G2235* | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- ASB10 | c.127C>A p.P43T | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP10B | c.2786G>A p.C929Y | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- B3GAT1 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.037); called by mutect2, varscan2
- BASP1 | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- BCL11A | c.1267G>T p.G423C (on ENST00000335712 / NM_001365609.1; = p.G457C on NM_018014.4) | Missense Mutation (SNP) | VAF 41/324 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- BLVRA | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 101/557 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BNIP1 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- BOC | c.368C>A p.T123K | Missense Mutation (SNP) | VAF 52/289 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- BRD1 | c.2804C>G p.A935G (on ENST00000216267 / NM_001349940.1; = p.A1066G on NM_001304808.3) | Missense Mutation (SNP) | VAF 74/502 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- C10orf90 | c.178G>C p.E60Q | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- C4orf48 | c.191T>A p.L64Q | Missense Mutation (SNP) | VAF 30/149 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNA1C | c.3391_3392del p.D1131Qfs*50 | Frame Shift Del (DEL) | VAF 24/116 reads (21%) | called by mutect2, pindel, varscan2
- CACNA1E | c.3076C>T p.P1026S | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- CADM2 | c.345G>C p.K115N (on ENST00000407528 / NM_001167674.2; = p.K117N on NM_153184.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CARS1 | c.25G>T p.G9C | Missense Mutation (SNP) | VAF 33/234 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC157 | c.1804C>T p.L602F | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC170 | c.1800G>T p.K600N | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, varscan2
- CCDC85A | c.1418G>T p.C473F | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CCL7 | c.266A>T p.H89L | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CCNF | c.1213A>T p.I405F | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2
- CCNO | c.816C>A p.D272E | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH20 | c.328G>T p.D110Y | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDHR2 | c.1125C>A p.Y375* | Nonsense Mutation (SNP) | VAF 33/183 reads (18%) | called by muse, mutect2, varscan2
- CENPJ | c.1852G>T p.V618F | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- CHEK2 | c.1282T>A p.C428S (on ENST00000382580 / NM_001005735.2; = p.C385S on NM_007194.4) | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- CHRNA4 | c.374T>A p.L125H | Missense Mutation (SNP) | VAF 67/367 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHST15 | c.725A>C p.H242P | Missense Mutation (SNP) | VAF 46/215 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CLIP2 | c.1164C>G p.H388Q | Missense Mutation (SNP) | VAF 67/402 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.216); called by muse, varscan2
- CLN8 | c.446G>T p.C149F | Missense Mutation (SNP) | VAF 76/322 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CMYA5 | c.8769dup p.G2924Rfs*2 | Frame Shift Ins (INS) | VAF 6/54 reads (11%) | called by mutect2, varscan2
- CNKSR2 | c.423G>C p.W141C | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CNTN3 | c.2708C>T p.P903L | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- CNTN4 | c.478A>C p.N160H | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP2 | c.429C>A p.D143E | Missense Mutation (SNP) | VAF 36/364 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.041); called by muse, mutect2
- COL12A1 | c.7250G>A p.W2417* | Nonsense Mutation (SNP) | VAF 35/204 reads (17%) | called by muse, mutect2, varscan2
- COL3A1 | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 71/458 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.65); called by muse, varscan2
- COMMD9 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.362); called by muse, mutect2, varscan2
- CPS1 | c.1537G>A p.A513T | Missense Mutation (SNP) | VAF 35/214 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.3140C>T p.P1047L (on ENST00000297405 / NM_001363185.1; = p.P943L on NM_052900.3) | Missense Mutation (SNP) | VAF 29/174 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- CYLD | c.1165A>G p.T389A | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.185); called by muse, mutect2
- CYP4F2 | c.1115+1G>A p.X372_splice | Splice Site (SNP) | VAF 18/91 reads (20%) | called by muse, mutect2, varscan2
- CYTL1 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- DAPK3 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 70/353 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- DENND11 | c.482A>G p.Y161C | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DIP2C | c.3716G>T p.C1239F | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DLX6 | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DNAH3 | c.5860C>A p.L1954M | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EMX2 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.039); called by muse, varscan2
- ENOX1 | c.929C>A p.A310D | Missense Mutation (SNP) | VAF 46/375 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, varscan2
- EPB41L3 | c.1393A>T p.I465F | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- ERCC6 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 93/477 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- ESR2 | c.213del p.Q72Rfs*18 | Frame Shift Del (DEL) | VAF 24/150 reads (16%) | called by mutect2, pindel, varscan2
- FAF1 | c.1653+1G>T p.X551_splice | Splice Site (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2
- FAM214A | c.299A>G p.Y100C | Missense Mutation (SNP) | VAF 61/344 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXL7 | c.1146dup p.A383Rfs*73 | Frame Shift Ins (INS) | VAF 41/204 reads (20%) | called by mutect2, varscan2
- FKTN | c.916T>A p.Y306N | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- FLNC | c.4349G>T p.G1450V | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FNDC7 | c.1987G>A p.G663S | Missense Mutation (SNP) | VAF 41/203 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FOXRED1 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 40/528 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- FRG2C | c.115C>A p.P39T | Missense Mutation (SNP) | VAF 57/818 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- GFRA3 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 82/445 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GHR | c.589A>C p.K197Q | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- GIMAP5 | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- GPATCH2 | c.1277+1G>T p.X426_splice | Splice Site (SNP) | VAF 21/90 reads (23%) | called by muse, mutect2, varscan2
- GPATCH2 | c.1277G>T p.R426M | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- GRM4 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 37/144 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- GRM6 | c.2202C>A p.D734E | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.029); called by muse, varscan2
- HCLS1 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 85/459 reads (19%) | SIFT tolerated (0.67); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- HDGFL1 | c.525G>T p.R175S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- HEATR5B | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 64/321 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- HECW1 | c.1244C>A p.P415Q | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- HIF3A | c.1559C>A p.P520H (on ENST00000377670 / NM_152795.4; = p.P451H on NM_022462.4) | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- HNRNPA2B1 | c.659G>T p.G220V (on ENST00000354667 / NM_031243.3; = p.G208V on NM_002137.4) | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- HOXD11 | c.435G>T p.E145D | Missense Mutation (SNP) | VAF 47/214 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGFN1 | c.228G>C p.K76N | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- IMPG2 | c.1232C>G p.S411C | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- INTS1 | c.2717C>T p.P906L | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JAM2 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- KBTBD11 | c.746A>T p.N249I | Missense Mutation (SNP) | VAF 67/352 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KCNK2 | c.182C>G p.T61R (on ENST00000444842 / NM_001017425.3; = p.T46R on NM_014217.4) | Missense Mutation (SNP) | VAF 41/350 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- KLHL4 | c.1711A>C p.K571Q | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- KMT2B | c.3003-7T>C | Splice Region (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2
- KRTAP13-2 | c.68C>A p.A23E | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.079); called by muse, mutect2
- LAMA5 | c.5850-2A>T p.X1950_splice | Splice Site (SNP) | VAF 38/105 reads (36%) | called by muse, mutect2, varscan2
- LAMB1 | c.4029C>G p.N1343K | Missense Mutation (SNP) | VAF 55/348 reads (16%) | SIFT tolerated (0.88); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LCK | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 59/258 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LEO1 | c.1394A>T p.Q465L | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LGR4 | c.2536G>A p.G846S | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.106); called by muse, mutect2
- LILRA6 | c.295C>A p.H99N | Missense Mutation (SNP) | VAF 106/594 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- LILRB1 | c.221T>C p.V74A (on ENST00000427581; = p.V38A on NM_006669.6) | Missense Mutation (SNP) | VAF 25/249 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.405); called by muse, mutect2
- LRP2 | c.1218del p.I406Mfs*12 | Frame Shift Del (DEL) | VAF 34/177 reads (19%) | called by mutect2, pindel, varscan2
- MAB21L1 | c.541C>G p.P181A | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP2 | c.876G>T p.M292I | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.037); called by muse, mutect2
- MARS2 | c.178A>T p.I60F | Missense Mutation (SNP) | VAF 48/176 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MED13L | c.5015C>A p.A1672D | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MFSD11 | c.782G>T p.G261V | Missense Mutation (SNP) | VAF 31/112 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- MGAM2 | c.5342G>T p.S1781I | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.786); called by muse, varscan2
- MLLT6 | c.339T>G p.H113Q | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- MPHOSPH8 | c.1642_1668del p.F548_D556del | In Frame Del (DEL) | VAF 10/100 reads (10%) | called by mutect2, pindel
- MRPS31 | c.684T>A p.F228L | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- MUC16 | c.33032G>C p.G11011A | Missense Mutation (SNP) | VAF 29/124 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MUC5AC | c.1414C>A p.L472M | Missense Mutation (SNP) | VAF 63/325 reads (19%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MUC7 | c.899C>A p.P300Q | Missense Mutation (SNP) | VAF 39/273 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- MUTYH | c.847G>T p.G283W | Missense Mutation (SNP) | VAF 112/689 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MYH1 | c.4813C>A p.L1605M | Missense Mutation (SNP) | VAF 61/286 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- MYH2 | c.2828C>G p.T943R | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- MYO5C | c.575A>T p.D192V | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- MYOCD | c.2452G>T p.G818* | Nonsense Mutation (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- MYOM3 | c.3152A>T p.N1051I | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.091); called by muse, mutect2
- NAV3 | c.3457G>T p.G1153* | Nonsense Mutation (SNP) | VAF 47/228 reads (21%) | called by muse, mutect2, varscan2
- NBPF15 | c.634T>C p.S212P | Missense Mutation (SNP) | VAF 93/720 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- NCAPH2 | c.1642_1655del p.E548Hfs*10 | Frame Shift Del (DEL) | VAF 12/122 reads (10%) | called by mutect2, pindel
- NEK7 | c.482-1G>T p.X161_splice | Splice Site (SNP) | VAF 20/83 reads (24%) | called by muse, mutect2, varscan2
- NELL2 | c.1372G>T p.V458F | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.825); called by muse, mutect2
- NFASC | c.1418T>A p.L473Q (on ENST00000339876 / NM_001378329.1; = p.L484Q on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 85/550 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- NOBOX | c.1882C>A p.L628I | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- NPAS4 | c.1411A>G p.T471A | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.522); called by muse, mutect2
- NTRK1 | c.2093G>C p.S698T | Missense Mutation (SNP) | VAF 92/326 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OBSL1 | c.5020C>T p.L1674F | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR10A5 | c.528C>A p.N176K | Missense Mutation (SNP) | VAF 40/341 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OR10G8 | c.434C>A p.T145N | Missense Mutation (SNP) | VAF 27/309 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.297); called by muse, mutect2
- OR2M3 | c.306C>A p.F102L | Missense Mutation (SNP) | VAF 53/352 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- OR4C46 | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 52/288 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- OR5H2 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- OTUD7A | c.805G>T p.E269* (on ENST00000307050 / NM_001382637.1; = p.E262* on NM_130901.3) | Nonsense Mutation (SNP) | VAF 44/181 reads (24%) | called by muse, mutect2, varscan2
- OXT | c.320C>A p.P107Q | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- P3H2 | c.1081T>A p.S361T | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2
- PABPC3 | c.1632G>T p.R544S | Missense Mutation (SNP) | VAF 45/217 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAK5 | c.189G>C p.Q63H | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PAMR1 | c.731G>T p.C244F | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PAPPA | c.3949C>A p.P1317T | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- PCDH10 | c.1390A>C p.S464R | Missense Mutation (SNP) | VAF 46/250 reads (18%) | SIFT tolerated (0.46); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PCDHB5 | c.1527C>G p.N509K | Missense Mutation (SNP) | VAF 71/686 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- PCDHGC4 | c.2047A>T p.R683W | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- PCLO | c.4202G>T p.S1401I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- PCSK1 | c.722T>C p.L241P | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDGFD | c.406G>T p.V136F | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- PHF2 | c.1290G>T p.Q430H | Missense Mutation (SNP) | VAF 26/261 reads (10%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.983); called by muse, mutect2
- PIGR | c.670del p.D224Mfs*15 | Frame Shift Del (DEL) | VAF 23/206 reads (11%) | called by mutect2, pindel, varscan2
- PLPPR3 | c.1133C>G p.P378R (on ENST00000520876 / NM_001270366.2; = p.P406R on NM_024888.2) | Missense Mutation (SNP) | VAF 42/240 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- POLR3C | c.1578_1582del p.Y526* | Nonsense Mutation (DEL) | VAF 24/179 reads (13%) | called by mutect2, pindel, varscan2
- PPP1R3G | c.621C>A p.S207R | Missense Mutation (SNP) | VAF 58/255 reads (23%) | SIFT tolerated (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRDM2 | c.1184G>C p.C395S | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- PRKD1 | c.985+4G>T | Splice Region (SNP) | VAF 11/90 reads (12%) | called by muse, mutect2, varscan2
- PROX1 | c.229G>T p.A77S | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PSG4 | c.387del p.D129Efs*6 | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | called by mutect2, pindel
- PTPRC | c.513C>A p.S171R | Missense Mutation (SNP) | VAF 175/723 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.143); called by mutect2, varscan2
- PZP | c.1978G>A p.A660T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- QRICH2 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.747); called by muse, mutect2
- RASSF8 | c.855G>T p.Q285H | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM27 | c.1541A>G p.Q514R | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- RELN | c.3129C>A p.C1043* | Nonsense Mutation (SNP) | VAF 87/533 reads (16%) | called by muse, mutect2, varscan2
- RGS6 | c.1389G>T p.K463N | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RHAG | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 47/281 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ROBO1 | c.4699G>T p.A1567S | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.275); called by muse, mutect2
- ROBO2 | c.1030G>C p.A344P | Missense Mutation (SNP) | VAF 42/279 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RP1 | c.1497C>G p.H499Q | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- RREB1 | c.3292A>C p.T1098P | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- RYR2 | c.1074C>A p.D358E | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SAGE1 | c.221-1G>T p.X74_splice | Splice Site (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- SHTN1 | c.1738G>T p.V580L | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- SIK2 | c.2621A>G p.Q874R | Missense Mutation (SNP) | VAF 75/427 reads (18%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- SLC18A3 | c.1228G>T p.D410Y | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC25A33 | c.256G>T p.G86* | Nonsense Mutation (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- SLC38A3 | c.855+4C>T | Splice Region (SNP) | VAF 46/229 reads (20%) | called by muse, mutect2, varscan2
- SLC6A1 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 52/279 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMC6 | c.2263G>T p.V755F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- SNAP91 | c.46A>T p.S16C | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- SNCAIP | c.2511C>A p.D837E | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SND1 | c.1429G>T p.D477Y | Missense Mutation (SNP) | VAF 29/160 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SOX6 | c.752T>C p.I251T | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.206); called by mutect2, varscan2
- SPATA31D1 | c.2922G>T p.L974F | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SPATA6 | c.529G>T p.G177C | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, varscan2
- ST8SIA6 | c.1054G>T p.D352Y | Missense Mutation (SNP) | VAF 46/273 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- STAC2 | c.178C>A p.L60I | Missense Mutation (SNP) | VAF 71/229 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, varscan2
- STK11 | c.616del p.A206Rfs*81 | Frame Shift Del (DEL) | VAF 14/67 reads (21%) | called by mutect2, pindel, varscan2
- STK40 | c.570+1G>A p.X190_splice | Splice Site (SNP) | VAF 26/153 reads (17%) | called by muse, mutect2, varscan2
- SULT1C4 | c.65T>A p.V22E | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- SYNE1 | c.18366G>T p.Q6122H (on ENST00000367255 / NM_182961.4; = p.Q6051H on NM_033071.3) | Missense Mutation (SNP) | VAF 45/228 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYT16 | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TAAR8 | c.101T>A p.L34Q | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TANC2 | c.4291G>A p.A1431T | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2
- TCP11X2 | c.1324del p.Q442Rfs*28 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | called by mutect2, varscan2
- TDRD15 | c.4475C>A p.P1492Q | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TENM3 | c.2158G>C p.G720R | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TLN2 | c.956A>T p.K319M | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TLR4 | c.2388G>T p.E796D (on ENST00000355622 / NM_138554.5; = p.E756D on NM_003266.4) | Missense Mutation (SNP) | VAF 55/241 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- TMEM26 | c.928G>C p.A310P | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TRAV22 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, varscan2
- TRIO | c.4412G>C p.S1471T | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- TRMT10A | c.829G>C p.G277R | Missense Mutation (SNP) | VAF 31/189 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- TRPS1 | c.2263A>G p.K755E (on ENST00000220888 / NM_001330599.2; = p.K768E on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 104/440 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TRPV6 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSHR | c.1490C>A p.A497D | Missense Mutation (SNP) | VAF 36/218 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TSHZ1 | c.644G>T p.G215V (on ENST00000580243 / NM_001308210.2; = p.G170V on NM_005786.6) | Missense Mutation (SNP) | VAF 61/198 reads (31%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- TTLL5 | c.1205C>T p.P402L | Missense Mutation (SNP) | VAF 39/233 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- TUBGCP2 | c.1566G>T p.M522I | Missense Mutation (SNP) | VAF 64/323 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, varscan2
- UNKL | c.134C>G p.A45G | Missense Mutation (SNP) | VAF 26/202 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- USH2A | c.7047G>T p.W2349C | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VCAN | c.876C>A p.D292E | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VSTM1 | c.262C>A p.P88T | Missense Mutation (SNP) | VAF 70/381 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- VWC2 | c.130G>T p.G44C | Missense Mutation (SNP) | VAF 47/211 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- YAP1 | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 69/423 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YWHAZ | c.27G>C p.K9N | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- ZC3HC1 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- ZFP14 | c.107G>T p.W36L | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZIM3 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ZMYM3 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- ZNF521 | c.1479G>C p.Q493H | Missense Mutation (SNP) | VAF 28/125 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF536 | c.3635C>A p.T1212K | Missense Mutation (SNP) | VAF 56/287 reads (20%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF585A | c.460G>T p.G154* (on ENST00000292841 / NM_001288800.2; = p.G99* on NM_152655.3) | Nonsense Mutation (SNP) | VAF 22/83 reads (27%) | called by muse, mutect2, varscan2
- ZNF606 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZNF804A | c.2647C>A p.P883T | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.003); called by mutect2, varscan2
- ZNF844 | c.480A>T p.E160D | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- ZNF99 | c.2226del p.F742Lfs*12 | Frame Shift Del (DEL) | VAF 17/135 reads (13%) | called by mutect2, varscan2
- ZP4 | c.1136C>A p.P379Q | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.977); called by muse, mutect2
- ABHD8 | c.399C>T p.P133= | Silent (SNP) | VAF 12/183 reads (7%) | catalogued as rs759388755, COSV53113287; called by muse, mutect2
- ADGRG3 | c.456C>A p.V152= | Silent (SNP) | VAF 28/294 reads (10%) | called by muse, mutect2
- ANK2 | c.603G>A p.R201= | Silent (SNP) | VAF 83/476 reads (17%) | called by muse, mutect2, varscan2
- ANKRD30B | c.1593C>A p.A531= | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- ANXA2 | c.994C>T p.L332= | Silent (SNP) | VAF 32/282 reads (11%) | called by muse, mutect2, varscan2
- ARHGAP22 | c.1101A>G p.A367= | Silent (SNP) | VAF 56/259 reads (22%) | called by muse, mutect2, varscan2
- BCL2 | c.114G>A p.A38= | Silent (SNP) | VAF 32/116 reads (28%) | catalogued as rs1169270253; called by muse, mutect2, varscan2
- BRS3 | c.1128C>T p.S376= | Silent (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- C10orf67 | c.237C>G p.G79= (on ENST00000323327; = p.G80= on NM_153714.3) | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs192695716; called by muse, mutect2, varscan2
- C17orf98 | c.183G>A p.P61= | Silent (SNP) | VAF 24/130 reads (18%) | catalogued as rs1364990920; called by muse, mutect2, varscan2
- C1orf167 | c.3735C>A p.A1245= | Silent (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- C5AR1 | c.195G>A p.E65= | Silent (SNP) | VAF 74/418 reads (18%) | catalogued as COSV61893055; called by muse, mutect2, varscan2
- CACNA1D | c.1968G>T p.L656= (on ENST00000350061 / NM_001128840.3; = p.L676= on NM_000720.4) | Silent (SNP) | VAF 55/316 reads (17%) | catalogued as rs1396889794; called by muse, mutect2, varscan2
- CCDC15 | c.2463A>T p.L821= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV61082266; called by muse, mutect2
- CCDC70 | c.420G>A p.Q140= | Silent (SNP) | VAF 18/125 reads (14%) | catalogued as COSV54430207; called by muse, mutect2, varscan2
- CEP128 | c.3150C>T p.F1050= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs776062756; called by muse, mutect2, varscan2
- CMA1 | c.414C>G p.V138= | Silent (SNP) | VAF 37/287 reads (13%) | called by muse, mutect2, varscan2
- CNGA3 | c.2007G>A p.V669= | Silent (SNP) | VAF 15/185 reads (8%) | called by muse, mutect2
- CRACR2A | c.1440C>G p.P480= | Silent (SNP) | VAF 88/353 reads (25%) | called by muse, mutect2, varscan2
- CTNNA2 | c.117C>T p.V39= | Silent (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- DENND1C | c.465C>A p.V155= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2
- DLGAP2 | c.447G>T p.P149= | Silent (SNP) | VAF 48/256 reads (19%) | catalogued as rs144322124; called by muse, mutect2, varscan2
- EID2B | c.441G>A p.T147= | Silent (SNP) | VAF 30/170 reads (18%) | called by muse, mutect2
- FABP1 | c.75G>T p.P25= | Silent (SNP) | VAF 7/46 reads (15%) | called by muse, mutect2
- FARP1 | c.1038G>A p.Q346= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- FBN1 | c.3153T>C p.F1051= | Silent (SNP) | VAF 142/485 reads (29%) | called by muse, mutect2, varscan2
- FOXD1 | c.759C>T p.A253= | Silent (SNP) | VAF 6/37 reads (16%) | called by muse, varscan2
- FREM1 | c.1719G>A p.K573= | Silent (SNP) | VAF 5/24 reads (21%) | called by muse, mutect2, varscan2
- GLS | c.201C>T p.P67= | Silent (SNP) | VAF 15/100 reads (15%) | called by muse, mutect2, varscan2
- GRIA1 | c.672C>T p.I224= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as rs147489207; called by muse, mutect2, varscan2
- GRIK4 | c.2613C>A p.P871= | Silent (SNP) | VAF 55/307 reads (18%) | catalogued as COSV70803085; called by muse, mutect2, varscan2
- GRIN2B | c.3054C>A p.I1018= | Silent (SNP) | VAF 36/243 reads (15%) | called by muse, mutect2, varscan2
- GRM6 | c.2155C>A p.R719= | Silent (SNP) | VAF 37/148 reads (25%) | catalogued as rs553937496; called by muse, varscan2
- GRM6 | c.1849C>A p.R617= | Silent (SNP) | VAF 58/341 reads (17%) | called by muse, mutect2, varscan2
- GRM8 | c.2187G>T p.R729= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- HCK | c.618G>A p.G206= | Silent (SNP) | VAF 67/251 reads (27%) | called by muse, mutect2, varscan2
- HECTD4 | c.11862G>T p.L3954= | Silent (SNP) | VAF 49/214 reads (23%) | called by muse, mutect2, varscan2
- HECW1 | c.3987C>A p.P1329= | Silent (SNP) | VAF 31/119 reads (26%) | called by muse, mutect2, varscan2
- HOXC13 | c.870C>T p.R290= | Silent (SNP) | VAF 89/523 reads (17%) | catalogued as COSV54500497; called by muse, mutect2, varscan2
- HOXD3 | c.375C>A p.T125= | Silent (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
- IGFBP1 | c.120C>A p.L40= | Silent (SNP) | VAF 84/466 reads (18%) | called by muse, mutect2, varscan2
- KLHL33 | c.528G>C p.R176= | Silent (SNP) | VAF 54/240 reads (23%) | called by muse, mutect2, varscan2
- KRT16 | c.123T>C p.R41= | Silent (SNP) | VAF 35/198 reads (18%) | catalogued as rs745323260; called by muse, mutect2, varscan2
- KRTAP12-1 | c.222G>T p.G74= | Silent (SNP) | VAF 36/203 reads (18%) | called by muse, mutect2, varscan2
- LAMA1 | c.7209T>C p.V2403= | Silent (SNP) | VAF 36/398 reads (9%) | called by muse, mutect2
- LMAN1L | c.1089C>A p.S363= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV59001682; called by muse, mutect2
- LMOD2 | c.1131C>A p.T377= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV71755774; called by muse, mutect2, varscan2
- LRP1B | c.318G>A p.G106= | Silent (SNP) | VAF 32/211 reads (15%) | catalogued as rs1015359466; called by muse, mutect2, varscan2
- LRRC8A | c.1749C>G p.V583= | Silent (SNP) | VAF 23/267 reads (9%) | called by muse, mutect2
- LYZL1 | c.381G>A p.A127= (on ENST00000375500; = p.A81= on NM_032517.6) | Silent (SNP) | VAF 31/191 reads (16%) | catalogued as rs771179887, COSV100973641; called by muse, mutect2, varscan2
- MUC16 | c.11682C>A p.I3894= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV67461673; called by muse, mutect2, varscan2
- MUC5AC | c.15654C>T p.A5218= | Silent (SNP) | VAF 23/139 reads (17%) | catalogued as rs768260323; called by muse, mutect2, varscan2
- MYH8 | c.1143A>T p.T381= | Silent (SNP) | VAF 53/281 reads (19%) | called by muse, mutect2, varscan2
- NOSIP | c.63G>A p.K21= | Silent (SNP) | VAF 49/263 reads (19%) | called by muse, mutect2, varscan2
- NPAP1 | c.3174C>A p.A1058= | Silent (SNP) | VAF 26/314 reads (8%) | called by muse, mutect2
- NPAS4 | c.1413G>A p.T471= | Silent (SNP) | VAF 26/156 reads (17%) | catalogued as rs371667911; called by muse, mutect2
- OR10Q1 | c.186G>T p.P62= | Silent (SNP) | VAF 36/182 reads (20%) | catalogued as COSV57469722; called by muse, mutect2, varscan2
- OR10T2 | c.828G>A p.V276= | Silent (SNP) | VAF 38/162 reads (23%) | called by muse, mutect2, varscan2
- OR2T3 | c.606G>T p.T202= | Silent (SNP) | VAF 94/389 reads (24%) | catalogued as rs1443833489, COSV62082972; called by muse, mutect2, varscan2
- OR52J3 | c.414G>A p.L138= | Silent (SNP) | VAF 26/150 reads (17%) | called by muse, mutect2
- OR5M8 | c.468G>T p.L156= | Silent (SNP) | VAF 39/235 reads (17%) | called by muse, mutect2, varscan2
- OTUD7A | c.1213C>T p.L405= (on ENST00000307050 / NM_001382637.1; = p.L398= on NM_130901.3) | Silent (SNP) | VAF 12/210 reads (6%) | called by muse, mutect2
- PDE2A | c.793C>T p.L265= | Silent (SNP) | VAF 18/228 reads (8%) | called by muse, mutect2
- PDE5A | c.336C>G p.P112= | Silent (SNP) | VAF 22/102 reads (22%) | called by muse, mutect2, varscan2
- PFN3 | c.120G>A p.L40= | Silent (SNP) | VAF 64/294 reads (22%) | catalogued as COSV53690685; called by muse, mutect2, varscan2
- PKD1 | c.6879G>T p.P2293= | Silent (SNP) | VAF 17/89 reads (19%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.3366G>T p.L1122= | Silent (SNP) | VAF 20/178 reads (11%) | called by muse, mutect2, varscan2
- PKN1 | c.2805C>T p.F935= | Silent (SNP) | VAF 20/86 reads (23%) | catalogued as COSV99466272; called by muse, mutect2
- PODN | c.1620G>A p.L540= (on ENST00000395871; = p.L492= on NM_153703.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/69 reads (16%) | called by muse, mutect2, varscan2
- PRICKLE1 | c.480G>T p.T160= | Silent (SNP) | VAF 39/269 reads (14%) | called by muse, mutect2, varscan2
- PRKN | c.768C>A p.R256= | Silent (SNP) | VAF 84/391 reads (21%) | catalogued as COSV58210051; called by muse, mutect2, varscan2
- PRUNE2 | c.1866C>A p.S622= | Silent (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2
- PTGER3 | c.1017G>A p.Q339= | Silent (SNP) | VAF 42/197 reads (21%) | catalogued as rs1466980813; called by muse, mutect2, varscan2
- PTGS1 | c.1698G>T p.L566= | Silent (SNP) | VAF 24/240 reads (10%) | called by muse, mutect2
- RBM6 | c.1167C>A p.G389= | Silent (SNP) | VAF 36/184 reads (20%) | catalogued as rs374615252; called by muse, mutect2, varscan2
- RBMXL2 | c.219C>G p.S73= | Silent (SNP) | VAF 80/512 reads (16%) | called by muse, mutect2, varscan2
- RICTOR | c.45A>G p.V15= | Silent (SNP) | VAF 62/253 reads (25%) | called by muse, mutect2, varscan2
- RP1L1 | c.1077G>T p.L359= | Silent (SNP) | VAF 40/157 reads (25%) | catalogued as rs894695633, COSV101223448, COSV66760595; called by muse, mutect2, varscan2
- SARNP | c.9C>T p.T3= | Silent (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- SCP2D1 | c.375G>T p.P125= | Silent (SNP) | VAF 41/246 reads (17%) | catalogued as COSV53856636, COSV53858807; called by muse, mutect2, varscan2
- SERPINA5 | c.702C>A p.P234= | Silent (SNP) | VAF 32/152 reads (21%) | catalogued as COSV100291582; called by muse, mutect2, varscan2
- SERPINB4 | c.265C>T p.L89= | Silent (SNP) | VAF 68/219 reads (31%) | catalogued as rs757375781; called by muse, mutect2, varscan2
- SETX | c.3246G>A p.E1082= | Silent (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- SIRPA | c.648G>T p.V216= | Silent (SNP) | VAF 102/670 reads (15%) | called by muse, mutect2, varscan2
- SLC12A1 | c.279A>T p.T93= | Silent (SNP) | VAF 6/102 reads (6%) | called by muse, mutect2
- SLC12A1 | c.1221C>A p.P407= | Silent (SNP) | VAF 55/184 reads (30%) | called by muse, mutect2, varscan2
- SLC17A6 | c.1383T>C p.P461= | Silent (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- SLC8A3 | c.2226G>C p.L742= (on ENST00000381269 / NM_183002.3; = p.L740= on NM_033262.4) | Silent (SNP) | VAF 48/220 reads (22%) | catalogued as rs946877246; called by muse, mutect2, varscan2
- SOX3 | c.1245C>A p.A415= | Silent (SNP) | VAF 27/77 reads (35%) | called by muse, mutect2, varscan2
- SPAG16 | c.96G>A p.T32= | Silent (SNP) | VAF 6/192 reads (3%) | called by muse, mutect2
- SPEF2 | c.4668G>A p.E1556= | Silent (SNP) | VAF 31/176 reads (18%) | catalogued as rs546118038; called by muse, mutect2, varscan2
- SRFBP1 | c.207A>G p.K69= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- SYT4 | c.222A>G p.G74= | Silent (SNP) | VAF 19/107 reads (18%) | called by muse, mutect2, varscan2
- TAL1 | c.903G>T p.P301= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as COSV53745002; called by muse, mutect2
- TEK | c.1359G>A p.V453= | Silent (SNP) | VAF 29/142 reads (20%) | called by muse, mutect2, varscan2
- TESMIN | c.393G>T p.A131= | Silent (SNP) | VAF 16/66 reads (24%) | called by muse, mutect2, varscan2
- TSSK2 | c.528C>T p.C176= | Silent (SNP) | VAF 21/148 reads (14%) | catalogued as rs148566995; called by muse, mutect2, varscan2
- TTC6 | c.1257C>A p.L419= (on ENST00000267368; = p.L1785= on NM_001310135.3) | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- TTN | c.31068T>A p.A10356= (on ENST00000591111; = p.A9429= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV60168049; called by muse, mutect2, varscan2
- TUBGCP3 | c.567A>T p.P189= | Silent (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2, varscan2
- UBR5 | c.3219A>G p.P1073= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs767676724; called by muse, mutect2, varscan2
- UMOD | c.303G>A p.S101= | Silent (SNP) | VAF 24/336 reads (7%) | catalogued as rs370600033, COSV100208412; called by muse, mutect2
- VCP | c.1212C>T p.H404= | Silent (SNP) | VAF 22/294 reads (7%) | catalogued as rs761986024; called by muse, mutect2
- VWA2 | c.1137G>T p.R379= | Silent (SNP) | VAF 52/286 reads (18%) | called by muse, mutect2, varscan2
- WDR43 | c.918C>T p.Y306= | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- WSCD2 | c.1657C>A p.R553= | Silent (SNP) | VAF 38/154 reads (25%) | called by muse, mutect2, varscan2
- WWC2 | c.168G>T p.G56= | Silent (SNP) | VAF 38/196 reads (19%) | catalogued as COSV100968463; called by muse, mutect2, varscan2
- ZNF174 | c.537C>T p.S179= | Silent (SNP) | VAF 29/160 reads (18%) | catalogued as rs370483754; called by muse, mutect2, varscan2
- ZNF296 | c.1053T>C p.T351= | Silent (SNP) | VAF 54/328 reads (16%) | catalogued as rs778386913; called by muse, mutect2, varscan2
- ZNF727 | c.570G>A p.Q190= | Silent (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- AC074085.2 | n.403G>T | RNA (SNP) | VAF 48/223 reads (22%) | called by muse, varscan2
- AL353804.7 | chrX:73851684 C>A | 3'Flank (SNP) | VAF 57/164 reads (35%) | called by muse, mutect2, varscan2
- ALDH1L1 | chr3:126181010 G>T | 5'Flank (SNP) | VAF 34/152 reads (22%) | catalogued as rs139632792; called by muse, mutect2, varscan2
- ALG2 | c.*1094G>T | 3'UTR (SNP) | VAF 10/141 reads (7%) | called by muse, mutect2
- ANKRD30B | c.2313+95T>C | Intron (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- ANO10 | c.1915-5842G>C | Intron (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- BEND7 | c.1082-2251G>A | Intron (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- C1QTNF3 | c.351+29G>T | Intron (SNP) | VAF 16/77 reads (21%) | called by muse, varscan2
- CTAGE11P | n.11C>A | RNA (SNP) | VAF 102/668 reads (15%) | called by muse, mutect2, varscan2
- CYB5RL | c.347+65C>T | Intron (SNP) | VAF 28/161 reads (17%) | catalogued as rs1329218162; called by muse, mutect2, varscan2
- DNAH14 | c.6033+1183G>C | Intron (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- EFHC1 | c.*153G>T | 3'UTR (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2, varscan2
- ETV7 | c.307+10A>T | Intron (SNP) | VAF 66/220 reads (30%) | called by muse, mutect2, varscan2
- GRIK1 | c.1251+53C>A | Intron (SNP) | VAF 12/119 reads (10%) | called by muse, mutect2, varscan2
- GRIN2A | c.*51G>T | 3'UTR (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- GVINP1 | n.3779G>T | RNA (SNP) | VAF 21/119 reads (18%) | called by muse, mutect2, varscan2
- HOATZ | chr11:111512997 C>G | 5'Flank (SNP) | VAF 32/218 reads (15%) | called by muse, mutect2, varscan2
- HOXA6 | chr7:27151586 C>T | 5'Flank (SNP) | VAF 16/149 reads (11%) | catalogued as rs1162323869; called by muse, mutect2, varscan2
- HSP90AA4P | n.2121G>T | RNA (SNP) | VAF 11/158 reads (7%) | called by muse, mutect2
- IGDCC4 | c.998-152G>T | Intron (SNP) | VAF 22/121 reads (18%) | called by muse, mutect2, varscan2
- KCNJ1 | c.*45A>T | 3'UTR (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- KRT18P23 | chr22:44571402 T>G | 3'Flank (SNP) | VAF 32/191 reads (17%) | called by muse, mutect2, varscan2
- LAMC2 | c.3070-26G>A | Intron (SNP) | VAF 50/345 reads (14%) | catalogued as rs746973333; called by muse, mutect2, varscan2
- LIPI | c.*28C>A | 3'UTR (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85440G>C | Intron (SNP) | VAF 48/235 reads (20%) | catalogued as rs780841406, COSV72275599; called by muse, varscan2
- MCAM | c.560-62C>T | Intron (SNP) | VAF 23/105 reads (22%) | catalogued as rs200234363; called by muse, mutect2, varscan2
- MDGA1 | c.2776+55G>A | Intron (SNP) | VAF 17/64 reads (27%) | catalogued as rs1187042868; called by muse, mutect2, varscan2
- MOK | c.411+79A>G | Intron (SNP) | VAF 13/66 reads (20%) | called by muse, mutect2, varscan2
- NAV3 | c.2024-12690G>T | Intron (SNP) | VAF 44/267 reads (16%) | called by muse, mutect2, varscan2
- NBPF22P | n.1275G>T | RNA (SNP) | VAF 24/577 reads (4%) | called by muse, mutect2
- OR2M1P | n.742G>T | RNA (SNP) | VAF 69/496 reads (14%) | called by muse, mutect2, varscan2
- P3H2 | c.-40C>G | 5'UTR (SNP) | VAF 26/225 reads (12%) | called by muse, varscan2
- PALM2AKAP2 | c.400+6941C>G | Intron (SNP) | VAF 33/128 reads (26%) | called by muse, mutect2, varscan2
- PKD1L2 | chr16:81137440 G>T | 5'Flank (SNP) | VAF 14/75 reads (19%) | catalogued as rs768434409; called by muse, mutect2, varscan2
- PRCD | chr17:76543946 C>A | 3'Flank (SNP) | VAF 90/664 reads (14%) | called by muse, mutect2, varscan2
- PTN | c.-126G>T | 5'UTR (SNP) | VAF 51/373 reads (14%) | catalogued as rs764590063; called by muse, mutect2, varscan2
- RC3H2 | c.961-103A>T | Intron (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | n.119G>T | RNA (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- SBSPON | c.-25C>T | 5'UTR (SNP) | VAF 17/100 reads (17%) | called by muse, mutect2, varscan2
- SLC7A5P2 | n.114A>T | RNA (SNP) | VAF 66/706 reads (9%) | catalogued as rs774185837; called by muse, mutect2
- SNX29P2 | n.514C>A | RNA (SNP) | VAF 18/231 reads (8%) | called by muse, mutect2, varscan2
- SOCS2 | c.-98T>G | 5'UTR (SNP) | VAF 17/544 reads (3%) | called by muse, mutect2
- TOPAZ1 | c.-36G>C | 5'UTR (SNP) | VAF 11/169 reads (7%) | called by muse, mutect2
- UBE2DNL | n.371C>G | RNA (SNP) | VAF 53/167 reads (32%) | called by muse, mutect2, varscan2
- UBE2G2 | c.126-1774G>T | Intron (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- Unknown | chr7:55699047 C>A | IGR (SNP) | VAF 27/179 reads (15%) | called by muse, mutect2, varscan2
- ZFP57 | c.*10C>G | 3'UTR (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
